Somatic mutation profile of tumor specimen TCGA-DW-7840-01A (aliquot TCGA-DW-7840-01A-11D-2136-08) from TCGA case TCGA-DW-7840, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.6 years (22,141 days).
Specimen TCGA-DW-7840-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7a22257-9cb9-47da-b75a-0e658a4e8dca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7840-10A (Blood Derived Normal), aliquot TCGA-DW-7840-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fd4767-b3fb-42e7-8746-b9f690489912

The open-access MAF lists 90 somatic variants for this specimen: 73 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 16, Frame Shift Del 10, Nonsense Mutation 2, Intron 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51910891; called by muse, mutect2, varscan2
- ADCY10 | c.380A>T p.H127L | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV63244833; called by muse, mutect2, varscan2
- ADTRP | c.583del p.A195Lfs*28 | Frame Shift Del (DEL) | VAF 79/262 reads (30%) | catalogued as COSV99995471; called by mutect2, pindel, varscan2
- ALKBH3 | c.216T>C p.I72= | Splice Region (SNP) | VAF 78/197 reads (40%) | catalogued as COSV57026406; called by muse, mutect2, varscan2
- ALOX5 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.778); catalogued as rs920933816, COSV65554366; called by muse, mutect2, varscan2
- ANKDD1A | c.669+2T>G p.X223_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as COSV60354321; called by muse, mutect2, varscan2
- ATP2A2 | c.751del p.Q251Kfs*3 | Frame Shift Del (DEL) | VAF 78/345 reads (23%) | catalogued as COSV100428991; called by mutect2, pindel, varscan2
- BRD2 | c.1334T>C p.V445A | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV66374484; called by muse, mutect2, varscan2
- C21orf58 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52451714; called by muse, mutect2, varscan2
- CAMTA1 | c.791G>C p.C264S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV57926067; called by muse, mutect2, varscan2
- CENPE | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV54389919; called by muse, mutect2, varscan2
- COL1A2 | c.3368G>T p.R1123L | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs145541630, COSV51965969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF12L1 | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV64422757; called by muse, mutect2, varscan2
- DNAAF5 | c.1628T>G p.M543R | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV52421242; called by muse, mutect2, varscan2
- DNMT3B | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV52417928, COSV52423180; called by muse, mutect2, varscan2
- EPHA7 | c.1845G>T p.E615D | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV65191545; called by muse, mutect2, varscan2
- FNBP1L | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53096648; called by muse, mutect2
- GPR37 | c.108C>G p.N36K | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV58259517; called by muse, mutect2, varscan2
- GRID1 | c.2102A>G p.Q701R | Missense Mutation (SNP) | VAF 149/400 reads (37%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.982); catalogued as COSV60052434; called by muse, mutect2, varscan2
- HMGCL | c.105T>G p.I35M | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV52527405; called by muse, mutect2, varscan2
- ICE1 | c.2545A>T p.T849S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV56832228; called by muse, mutect2, varscan2
- IFITM1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV60249982, COSV60250085; called by muse, mutect2, varscan2
- IGDCC4 | c.2089A>T p.K697* | Nonsense Mutation (SNP) | VAF 42/106 reads (40%) | catalogued as COSV61539196; called by muse, mutect2, varscan2
- IKBKE | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV65626986; called by muse, mutect2, varscan2
- ITGA1 | c.1873G>T p.G625W | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50897714; called by muse, mutect2, varscan2
- LHFPL2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV66716305; called by muse, mutect2, varscan2
- LRBA | c.1780C>A p.L594M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV63964648; called by muse, mutect2, varscan2
- LRP6 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 154/277 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs758242097, COSV53787948; called by muse, mutect2, varscan2
- LSG1 | c.659A>C p.E220A | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV54572671; called by muse, mutect2, varscan2
- MAP2K5 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV51622712; called by muse, mutect2, varscan2
- MAP3K4 | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV62335593, COSV62338386; called by muse, mutect2, varscan2
- MISP | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV53122291; called by muse, mutect2, varscan2
- MMP24 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773128; called by muse, mutect2, varscan2
- MTIF2 | c.1480T>C p.F494L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55054202; called by muse, mutect2, varscan2
- NRAP | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63493864; called by muse, mutect2, varscan2
- PATJ | c.4721T>C p.L1574S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57171990; called by muse, mutect2, varscan2
- PC | c.1507T>A p.Y503N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58922884; called by muse, mutect2, varscan2
- PHACTR4 | c.118T>C p.F40L (on ENST00000373839 / NM_001350159.2; = p.F50L on NM_023923.4) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65785096; called by muse, mutect2, varscan2
- PHLDB1 | c.2791A>T p.M931L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV61881787; called by muse, mutect2, varscan2
- PKD1L1 | c.6388C>G p.Q2130E | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV56977653; called by muse, mutect2, varscan2
- PPFIA2 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773591412, COSV61027352; called by muse, mutect2, varscan2
- PUM1 | c.3523T>A p.L1175I | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV57091141; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs578182809, COSV51487681, COSV51488619; called by muse, mutect2, varscan2
- RASGRF1 | c.3740A>G p.Y1247C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67251218; called by mutect2, varscan2
- RASSF9 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs367564230, COSV63436027; called by muse, mutect2, varscan2
- RBM15 | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV63924432; called by muse, mutect2, varscan2
- RCHY1 | c.565T>G p.S189A | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61009530; called by muse, mutect2, varscan2
- RERE | c.1711A>T p.S571C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61950626; called by muse, mutect2, varscan2
- SETX | c.6602A>G p.K2201R | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56394482; called by muse, mutect2, varscan2
- SIGIRR | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1045992661, COSV58990015; called by muse, mutect2, varscan2
- SLC22A7 | c.583T>C p.Y195H (on ENST00000372585 / NM_153320.2; = p.Y193H on NM_006672.3) | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1378167525, COSV65356279; called by muse, mutect2, varscan2
- SLC30A6 | c.580T>A p.F194I | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV50874551; called by muse, mutect2, varscan2
- SMARCA4 | c.3059A>G p.D1020G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV60808877; called by muse, mutect2, varscan2
- SOX30 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV53939594; called by muse, mutect2
- SUV39H2 | c.670A>T p.T224S (on ENST00000354919 / NM_001193424.2; = p.T164S on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as COSV57955503; called by muse, mutect2, varscan2
- SUV39H2 | c.671C>T p.T224I (on ENST00000354919 / NM_001193424.2; = p.T164I on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.266); catalogued as rs1219651240, COSV57955520; called by muse, mutect2, varscan2
- TECPR2 | c.2591G>T p.W864L | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63974192; called by muse, mutect2, varscan2
- TECPR2 | c.2592G>T p.W864C | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63974196; called by muse, mutect2, varscan2
- TFRC | c.1685A>T p.D562V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV64056461; called by muse, mutect2
- TRIM3 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61985603; called by muse, mutect2, varscan2
- TSC1 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs377279170; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TUBB4A | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV51165975; called by muse, mutect2, varscan2
- WWC2 | c.1291T>A p.S431T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV66716619; called by muse, mutect2, varscan2
- ZNF443 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV56894348; called by muse, mutect2, varscan2
- CDIN1 | c.672_702del p.S224Rfs*11 (on ENST00000437989; = p.S126Rfs*11 on NM_032499.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/127 reads (9%) | called by mutect2, pindel
- CRYBG1 | c.2760del p.N920Kfs*7 | Frame Shift Del (DEL) | VAF 51/154 reads (33%) | called by mutect2, pindel, varscan2
- EP300 | c.6450_6462del p.Q2151Sfs*7 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- IL36RN | c.405del p.Q135Hfs*37 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- PC | c.3088dup p.L1030Pfs*3 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- RFPL3 | c.327_328del p.K109Nfs*33 (on ENST00000249007 / NM_001098535.1; = p.K80Nfs*33 on NM_006604.2) | Frame Shift Del (DEL) | VAF 67/195 reads (34%) | called by mutect2, pindel, varscan2
- SGK2 | c.832del p.W278Gfs*78 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- SOBP | c.389del p.L130* | Frame Shift Del (DEL) | VAF 89/291 reads (31%) | called by mutect2, pindel, varscan2
- SRRT | c.2319_2323del p.A774Dfs*62 | Frame Shift Del (DEL) | VAF 36/217 reads (17%) | called by mutect2, pindel, varscan2
- ABTB1 | c.684C>A p.I228= (on ENST00000232744 / NM_172027.3; = p.I86= on NM_032548.3) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV51742896; called by muse, mutect2, varscan2
- BMP2K | c.1140T>C p.T380= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV58599253; called by muse, mutect2, varscan2
- CUL2 | c.957C>A p.I319= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV66081006; called by muse, mutect2, varscan2
- KIAA1217 | c.5751T>C p.H1917= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs1413791852, COSV56823617; called by muse, mutect2, varscan2
- KRTAP10-12 | c.15C>T p.S5= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as rs372249758; called by muse, mutect2, varscan2
- MYH8 | c.1857T>A p.T619= | Silent (SNP) | VAF 73/137 reads (53%) | catalogued as COSV67972306; called by muse, mutect2, varscan2
- PCDHB14 | c.2130G>C p.A710= | Silent (SNP) | VAF 101/293 reads (34%) | catalogued as COSV53388979, COSV53391285, COSV99506260; called by muse, mutect2, varscan2
- RCE1 | c.837A>C p.P279= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV58994131; called by muse, mutect2, varscan2
- SH3KBP1 | c.915C>A p.G305= | Silent (SNP) | VAF 34/42 reads (81%) | catalogued as COSV65644595; called by muse, mutect2, varscan2
- SYT14 | c.651T>C p.S217= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV55063521; called by muse, mutect2, varscan2
- TNS1 | c.1197G>C p.T399= | Silent (SNP) | VAF 93/225 reads (41%) | catalogued as COSV50730634, COSV50765431; called by muse, mutect2
- TRAV9-2 | c.210G>A p.T70= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs554640975; called by muse, mutect2, varscan2
- UCK1 | c.309C>T p.N103= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as COSV64736356; called by muse, mutect2, varscan2
- USP34 | c.5502G>A p.K1834= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs771598551, COSV68406409; called by muse, mutect2, varscan2
- ZNF557 | c.1116T>C p.S372= (on ENST00000414706 / NM_001044388.2; = p.S379= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV53275423; called by muse, mutect2, varscan2
- ZNRF3 | c.1770C>G p.L590= (on ENST00000544604 / NM_001206998.2; = p.L490= on NM_032173.3) | Silent (SNP) | VAF 78/219 reads (36%) | catalogued as COSV60438299; called by muse, mutect2, varscan2
- CFAP74 | c.2176+67G>A | Intron (SNP) | VAF 56/167 reads (34%) | catalogued as COSV54566480; called by muse, mutect2, varscan2
